CCDI case PBBUND — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8dcacdb0-85ac-403e-b8a1-d9f25ad8554a

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,876 days).

Biospecimens (3 samples)
- Sample 0DHQDH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHQE5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHQEK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
